Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6367, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6367-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. PROSTATE
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES

CGA - G9 - 6367

SPECIMEN(S):

- A. PROSTATE
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES

GROSS DESCRIPTION:

A. PROSTATE

Received fresh is a 37g resected prostate measuring 4.5cm from right to left, 4.2cm from anterior to posterior, and 3cm from apex to base, with attached right and left seminal vesicles and vas deferens. The specimen is inked as follows: Anterior-Orange, Posterior-Black, Apex-Red, Base-Blue, Right-Green, and Left-Yellow. After removal of the apex and base, the remaining prostate weight is 22. The specimen is serially sectioned from apex to base to reveal firm tan fibrous parenchyma. No obvious lesions or nodules are grossly identified. The attached right and left seminal vesicles are 4 x 1.5 x 0.8cm and 3.5 x 2.5 x 1cm, respectively, are sectioned to beige tan cystic tissue with no gross evidence of tumor involvement. The attached right and left segments of vas deferens are 1 x 0.6cm and 1.2 x 0.6cm, respectively, are sectioned to reveal firm tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Level II). The remainder is submitted as follows:

- A1: right apex
- A2: left apex
- A3: Level I right anterior
- A4: Level I right posterior
- A5: Level I left anterior
- A6: Level I left posterior
- A7: Level II right anterior capsule
- A8: Level II right posterior capsule
- A9: Level II left anterior capsule
- A10: Level II left posterior capsule
- A11: Level III right anterior
- A12: Level III right posterior
- A13: Level III left anterior
- A14: Level III left posterior
- A15: right base with periurethral margin
- A16-A17: left base with periurethral margin
- A18: right lateral base
- A19: left lateral base
- A20: right base
- A21: left base
- A22: right seminal vesicle and vas deferens
- A23: left seminal vesicle and vas deferens

B. RIGHT PELVIC LYMPH NODES

Received in formalin are multiple tan pink soft tissue fragments aggregating to 5 x 3 x 1cm. Dissection reveals 1 lymph node 1 x 1 x 1cm.

- B1: 1 lymph node
- B2-B3: remainder of specimen

C. LEFT PELVIC LYMPH NODES

Received in formalin are three tan pink lymph nodes ranging from 0.4 x 0.3 x 0.3cm to 2 x 2 x 1.5cm.

- C1: 2 lymph nodes
- C2: 1 lymph node

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON SCORE 4 + 5 = 9, WITH TERTIARY GLEASON GRADE 3.
- TUMOR INVOLVES BILATERAL LOBES AND ~ 25% OF THE PROSTATE.
- EXTRAPROSTATIC EXTENSION IS PRESENT.
- TUMOR IS PRESENT AT INKED MARGINS.

[page 2 of 2]
- BILATERAL SEMINAL VESICLES, NO TUMOR SEEN.

NOTE: Tumor with cautery artifact is present at the inked margin in slides A6 (left posterior) and A19 (left base (bladder neck)), each involving less than one millimeter of the inked margin. Cytokeratin AE1/3 stains highlight the tumor near but not at the inked margins in slides A12 and A14.

B. LYMPH NODES, RIGHT PELVIC, EXCISION:
- THREE LYMPH NODES, NO TUMOR SEEN (0/3).

C. LYMPH NODES, LEFT PELVIC, EXCISION:
- TWO LYMPH NODES, NO TUMOR SEEN (0/2).

SYNOPTIC REPORT - PROSTATE GLAND

Location: right and left lobes from apex to base

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 25%

Gleason Grade/Sum:: Grade 4 + 5 , Sum 9 /10; Tertiary grade 3

High Grade PIN Present: No

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Yes

Details: left apex, left posterior, right posterior

Bladder Neck Involved: Yes

Margins Involvement: Yes

Location: see above

Linear Distance: Diffuse (>10mm or Multifocal)

Frozen Performed: No

Lymph Nodes: Negative Right 0 / 3 Left 0 / 2

Other Pathologic Findings: BPH

Pathological Staging (pTNM): T 3a N 0 M X

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Prostate carcinoma

Source: NCI Genomic Data Commons file 582e9240-05d6-4885-8331-7bbe216a8cd0 (TCGA-G9-6367.1306F52C-6633-4CA8-8998-C5306E0C34BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).